Somatic mutation profile of tumor specimen MMRF_1447_1_BM_CD138pos (aliquot MMRF_1447_1_BM_CD138pos_T1_KAS5U_L01375) from MMRF case MMRF_1447, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.2 years (26,015 days).
Specimen MMRF_1447_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57043d33-a4c7-42c6-bdf1-af107993d97c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1447_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1447_1_PB_Whole_C2_KAS5U_L01387; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dde0a501-599a-40d2-8782-958f741dc50c

The open-access MAF lists 146 somatic variants for this specimen: 58 protein-altering or splice-affecting, 13 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 43, Intron 15, Silent 13, 5'Flank 8, Nonsense Mutation 6, 3'Flank 3, 5'UTR 3, RNA 3, Splice Region 2, Frame Shift Del 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TGFBR2 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | catalogued as rs863223852, CM063204, COSV55443474; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CCDC170 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749377952, COSV99498579; called by muse, mutect2, varscan2
- CCDC185 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs375462609; called by muse, mutect2, varscan2
- CD93 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as rs1402842521; called by muse, mutect2, varscan2
- CNOT9 | c.255C>G p.H85Q | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV55301573; called by muse, mutect2, varscan2
- DMXL2 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753290975, COSV51844140; called by muse, mutect2
- DNAH5 | c.5147G>A p.R1716Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM065123, COSV104370699; called by muse, mutect2, varscan2
- DUOX2 | c.3307C>T p.R1103C | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs144923217; called by muse, mutect2, varscan2
- DUSP2 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs991800580; called by muse, mutect2, varscan2
- EIF4G1 | c.1864T>C p.F622L (on ENST00000346169 / NM_198241.3; = p.F426L on NM_004953.5) | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV59993188; called by muse, mutect2, varscan2
- FTMT | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs754484196, COSV100360367; called by muse, mutect2, varscan2
- HSPB1 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs1405359814, CM163652; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2A | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as rs1361403705; called by muse, varscan2
- LAMB2 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757136658, COSV59734116; called by muse, mutect2
- MAPRE1 | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 104/198 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1409080565; called by muse, mutect2, varscan2
- MIOS | c.194G>A p.C65Y | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs955701689; called by muse, mutect2, varscan2
- MRPS30 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs190648137; called by muse, mutect2, varscan2
- OLFM1 | c.896C>T p.S299L (on ENST00000371793 / NM_001282611.2; = p.S281L on NM_014279.5) | Missense Mutation (SNP) | VAF 33/598 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV99424290; called by muse, mutect2
- POLN | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1257831432; called by muse, mutect2, varscan2
- SCN9A | c.5350G>A p.E1784K (on ENST00000303354; = p.E1773K on NM_002977.3) | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV57620961; called by muse, mutect2, varscan2
- SYNGAP1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53381847; called by muse, mutect2, varscan2
- TSPYL6 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 125/317 reads (39%) | catalogued as COSV100336636; called by muse, mutect2, varscan2
- XIRP2 | c.9416C>T p.A3139V (on ENST00000628543; = p.A3314V on NM_152381.6) | Missense Mutation (SNP) | VAF 86/116 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778378205, COSV99749579; called by muse, mutect2, varscan2
- ZBED9 | c.2909C>T p.S970F | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71729413; called by muse, mutect2, varscan2
- ZNF462 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 19/333 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.832); catalogued as rs139158101; called by muse, mutect2
- AC004997.1 | c.955_956del p.L319Vfs*28 | Frame Shift Del (DEL) | VAF 45/101 reads (45%) | called by mutect2, pindel, varscan2
- ATP2A3 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 30/44 reads (68%) | called by muse, mutect2, varscan2
- CIP2A | c.1905C>T p.S635= | Splice Region (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- CLEC14A | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- DRC7 | c.509C>A p.S170* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- FOXO1 | c.228G>C p.L76F | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FOXO1 | c.121A>C p.S41R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FRMPD2 | c.1581G>A p.W527* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- FSIP2 | c.3743C>T p.S1248F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- H3C4 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IGLV3-1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- KLHL28 | c.901G>T p.V301L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2A | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.039); called by muse, varscan2
- LAMA3 | c.4085G>T p.G1362V | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- LRRC58 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.272); called by muse, mutect2
- MEX3A | c.89G>C p.G30A | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MTCH2 | c.83T>G p.I28S | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MTNR1A | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MYH2 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- NDC1 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OCM2 | c.143del p.F48Sfs*4 | Frame Shift Del (DEL) | VAF 91/345 reads (26%) | called by mutect2, pindel, varscan2
- RNPC3 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RSRC1 | c.175T>G p.S59A | Missense Mutation (SNP) | VAF 70/100 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RYR2 | c.1011A>T p.K337N | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SLC24A3 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLMAP | c.1417T>A p.L473M (on ENST00000428312 / NM_001377924.1; = p.L535M on NM_007159.5) | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATS1 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.726); called by muse, mutect2
- TLR7 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPS1 | c.3700A>T p.M1234L (on ENST00000220888 / NM_001330599.2; = p.M1247L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- ZGRF1 | c.351T>C p.T117= | Splice Region (SNP) | VAF 2/13 reads (15%) | called by muse, mutect2
- ZNF749 | c.2035T>G p.Y679D | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDHR5 | c.33G>A p.L11= | Silent (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- CSF1R | c.399G>T p.V133= | Silent (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- CSMD3 | c.1818C>T p.G606= (on ENST00000297405 / NM_001363185.1; = p.G502= on NM_052900.3) | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as rs373699127; called by muse, mutect2, varscan2
- DMTN | c.1068C>A p.T356= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- GPRASP2 | c.2224C>T p.L742= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- IGLV3-1 | c.153T>C p.A51= | Silent (SNP) | VAF 44/80 reads (55%) | catalogued as rs571682243; called by muse, varscan2
- RAI1 | c.1575G>A p.L525= | Silent (SNP) | VAF 53/134 reads (40%) | called by muse, mutect2, varscan2
- SH3RF2 | c.2040C>T p.S680= | Silent (SNP) | VAF 210/403 reads (52%) | catalogued as COSV63039163; called by muse, mutect2, varscan2
- SLC12A2 | c.435C>T p.D145= | Silent (SNP) | VAF 62/130 reads (48%) | catalogued as rs750869343; called by muse, mutect2, varscan2
- SOWAHD | c.480C>T p.R160= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- TONSL | c.1500G>A p.L500= | Silent (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- TXNRD3 | c.457T>C p.L153= | Silent (SNP) | VAF 33/403 reads (8%) | called by muse, mutect2
- ZNF347 | c.396G>A p.R132= | Silent (SNP) | VAF 20/315 reads (6%) | called by muse, mutect2
- ABCG1 | c.538-66G>A | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- ABHD2 | c.*1147G>T | 3'UTR (SNP) | VAF 15/112 reads (13%) | called by muse, mutect2, varscan2
- ABI2 | c.725+49C>T | Intron (SNP) | VAF 55/387 reads (14%) | called by muse, mutect2, varscan2
- AC011487.2 | chr19:53600217 G>A | 3'Flank (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- AC087482.1 | n.473G>A | RNA (SNP) | VAF 8/42 reads (19%) | catalogued as rs1039721241; called by muse, mutect2, varscan2
- AGAP1 | c.-38G>A | 5'UTR (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- AGPAT4 | c.348+125G>A | Intron (SNP) | VAF 8/164 reads (5%) | catalogued as rs1487703554; called by muse, mutect2
- AL359195.2 | n.3061C>T | RNA (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
- ARMC5 | chr16:31458307 T>A | 5'Flank (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- ASPH | c.*63G>A | 3'UTR (SNP) | VAF 16/75 reads (21%) | catalogued as COSV57982163; called by muse, mutect2, varscan2
- B3GALT2 | c.*1191C>A | 3'UTR (SNP) | VAF 27/79 reads (34%) | catalogued as rs894676564; called by muse, mutect2, varscan2
- BCL11A | chr2:60452214 G>A | 3'Flank (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021131 T>C | 5'Flank (SNP) | VAF 94/98 reads (96%) | catalogued as COSV55848583; called by muse, mutect2, varscan2
- C14orf132 | chr14:96089728 C>T | 3'Flank (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- C4orf45 | c.*173G>A | 3'UTR (SNP) | VAF 9/227 reads (4%) | called by muse, mutect2
- C5orf64 | n.512+51989G>C | Intron (SNP) | VAF 15/243 reads (6%) | called by muse, mutect2
- CAMK4 | c.*9179A>G | 3'UTR (SNP) | VAF 68/280 reads (24%) | called by muse, mutect2, varscan2
- CBFB | c.165+69C>A | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as rs1248681069; called by muse, mutect2, varscan2
- CCL20 | c.*308del | 3'UTR (DEL) | VAF 20/146 reads (14%) | called by mutect2, pindel, varscan2
- CDIN1 | chr15:36579833 C>T | 5'Flank (SNP) | VAF 7/142 reads (5%) | called by muse, mutect2
- CEP170 | c.*476T>C | 3'UTR (SNP) | VAF 58/229 reads (25%) | catalogued as rs1479860688; called by muse, mutect2, varscan2
- CNST | c.*2435A>G | 3'UTR (SNP) | VAF 25/70 reads (36%) | catalogued as rs1182010548; called by muse, mutect2, varscan2
- DAW1 | c.973+5094C>T | Intron (SNP) | VAF 134/209 reads (64%) | called by muse, mutect2, varscan2
- DCHS1 | c.*348T>G | 3'UTR (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- DNER | c.*211C>T | 3'UTR (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- DST | c.21800-22T>C | Intron (SNP) | VAF 211/328 reads (64%) | called by muse, mutect2, varscan2
- FAM102A | c.*2188_*2189del | 3'UTR (DEL) | VAF 106/250 reads (42%) | catalogued as rs1374789516; called by pindel, varscan2
- FAM131A | chr3:184338734 C>T | 5'Flank (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- FBXL15 | c.-325T>G | 5'UTR (SNP) | VAF 51/105 reads (49%) | called by muse, mutect2, varscan2
- FBXO32 | c.*3501T>G | 3'UTR (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- FCRL5 | c.*659A>G | 3'UTR (SNP) | VAF 41/99 reads (41%) | called by muse, mutect2, varscan2
- FEM1C | c.*167A>G | 3'UTR (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- FOXK1 | c.*6848G>T | 3'UTR (SNP) | VAF 11/88 reads (13%) | catalogued as rs968064931; called by muse, mutect2, varscan2
- HJURP | c.*108T>A | 3'UTR (SNP) | VAF 54/462 reads (12%) | called by muse, mutect2, varscan2
- HNRNPLL | c.*1595A>C | 3'UTR (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- ITPKB | c.*2061T>A | 3'UTR (SNP) | VAF 34/49 reads (69%) | called by muse, mutect2, varscan2
- KCNA3 | c.*170G>A | 3'UTR (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- KCNE4 | c.*199G>A | 3'UTR (SNP) | VAF 45/118 reads (38%) | called by muse, mutect2, varscan2
- KIAA1549L | c.*4609T>C | 3'UTR (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- LGR6 | c.1137-66C>T | Intron (SNP) | VAF 12/41 reads (29%) | catalogued as rs889211936; called by muse, mutect2, varscan2
- LPGAT1 | c.*6210T>C | 3'UTR (SNP) | VAF 18/97 reads (19%) | called by muse, mutect2, varscan2
- LPXN | c.*176T>G | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- LRFN5 | c.*239del | 3'UTR (DEL) | VAF 16/36 reads (44%) | catalogued as rs201977258; called by mutect2, varscan2
- MAPK14 | c.*496T>C | 3'UTR (SNP) | VAF 34/111 reads (31%) | called by muse, mutect2, varscan2
- MKRN3 | c.*517A>T | 3'UTR (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- MYO16 | c.*689G>A | 3'UTR (SNP) | VAF 44/84 reads (52%) | called by muse, mutect2, varscan2
- NLK | c.*1216T>C | 3'UTR (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- NTRK3 | c.*13638C>T | 3'UTR (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- ORAI2 | c.*3237C>G | 3'UTR (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- PHLDB1 | c.2737-82T>G | Intron (SNP) | VAF 12/105 reads (11%) | catalogued as COSV61878616; called by muse, mutect2
- PRPF38A | c.*1168G>C | 3'UTR (SNP) | VAF 42/43 reads (98%) | catalogued as rs571218180; called by muse, mutect2, varscan2
- PRR3 | c.*1108T>G | 3'UTR (SNP) | VAF 32/60 reads (53%) | called by muse, varscan2
- PSMD9 | chr12:121888639 C>A | 5'Flank (SNP) | VAF 49/90 reads (54%) | called by muse, mutect2, varscan2
- RBM10 | c.-131G>A | 5'UTR (SNP) | VAF 10/15 reads (67%) | catalogued as COSV99333288; called by muse, mutect2, varscan2
- RGP1 | c.*3192G>A | 3'UTR (SNP) | VAF 65/321 reads (20%) | called by muse, mutect2, varscan2
- RNASEL | c.*223T>G | 3'UTR (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- RNF169 | c.*4056A>C | 3'UTR (SNP) | VAF 7/34 reads (21%) | catalogued as rs200744330; called by mutect2, varscan2
- RNU6-389P | chr7:55681606 C>T | 5'Flank (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- SKP1 | c.457-326G>A | Intron (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- SPART | c.*861T>G | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- STAG3L4 | n.2065A>G | RNA (SNP) | VAF 28/320 reads (9%) | called by muse, mutect2
- SYNE1 | c.4311-95C>T | Intron (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- SYNRG | c.*935C>T | 3'UTR (SNP) | VAF 26/57 reads (46%) | catalogued as rs754837486; called by muse, mutect2, varscan2
- TAOK3 | c.1195-48G>A | Intron (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- TBX6 | chr16:30091418 del CCGGGAGGCTTCATTAGCCTCGA | 5'Flank (DEL) | VAF 14/162 reads (9%) | called by mutect2, pindel
- TCP10L2 | c.*476A>T | 3'UTR (SNP) | VAF 201/346 reads (58%) | catalogued as rs1170811334; called by muse, mutect2, varscan2
- TMEM139 | c.*18T>A | 3'UTR (SNP) | VAF 56/776 reads (7%) | called by muse, mutect2
- TUSC3 | c.1028+148T>C | Intron (SNP) | VAF 49/53 reads (92%) | called by muse, mutect2, varscan2
- UBASH3B | c.*2312T>C | 3'UTR (SNP) | VAF 72/115 reads (63%) | called by muse, mutect2, varscan2
- UBXN6 | c.1201-10C>G | Intron (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- USP14 | chr18:158503 C>T | 5'Flank (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- ZBED4 | c.*1176del | 3'UTR (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- ZFPL1 | c.-8-110G>T | Intron (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- ZMYM5 | c.*391C>A | 3'UTR (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- ZXDA | c.*659C>A | 3'UTR (SNP) | VAF 50/51 reads (98%) | called by muse, mutect2, varscan2
